Gene-level copy-number profile of tumor specimen MP2PRT-PATEMU-TMP1-A from MP2PRT case MP2PRT-PATEMU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,631 days).
Specimen MP2PRT-PATEMU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c9ffa59-6256-46f1-93c5-a5779e91482c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATEMU-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/f8291c9a-87e3-4e62-8f58-bfcad7fab9f0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 7; copy number 2: 178; copy number 3: 8; copy number 4: 38,530; copy number 5: 182; copy number 6: 16,147; copy number 7: 207; copy number 8: 3,062; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr9:22,046,758–22,046,901, 1 gene (within-gene range 0–1): AL354709.1.
- chr11:90,017,611–90,098,817, 9 genes: AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–5): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:105,851,705–106,122,709, 61 genes (within-gene range 0–6) (broad region; genes not listed).
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–2): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,095,305–13,120,807, 2 genes, copy number 9: ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
